Somatic mutation profile of tumor specimen 0DVM1K from CCDI case PBCNAX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 16.0 years (5,840 days).
Specimen 0DVM1K: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17f350a8-1e04-442f-903a-2f3cccbe7204.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVM1W (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47315eab-6f5a-4c04-b6b6-f7379a148e4f

The open-access MAF lists 49 somatic variants for this specimen: 30 protein-altering or splice-affecting, 7 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 7, Intron 6, 3'UTR 4, Frame Shift Ins 1, Frame Shift Del 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AEBP2 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as rs754732926, COSV99857986; called by muse, mutect2, varscan2
- B4GALT1 | c.17C>A p.P6Q | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.009); catalogued as rs1303485836, COSV65707869; called by muse, mutect2, varscan2
- C2orf74 | c.107dup p.L36Ffs*3 | Frame Shift Ins (INS) | VAF 46/215 reads (21%) | catalogued as rs1265298443; called by mutect2, varscan2
- CNMD | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 58/263 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs766244515; called by muse, mutect2, varscan2
- DENND2A | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 48/280 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs573861843, COSV52054083; called by muse, mutect2, varscan2
- DIP2C | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs888425993, COSV55159684; called by muse, mutect2, varscan2
- KRT86 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 57/454 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs778504570; called by muse, mutect2, varscan2
- MYO7A | c.5974T>A p.F1992I | Missense Mutation (SNP) | VAF 69/232 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.962); catalogued as rs771906493; called by muse, mutect2, varscan2
- R3HDM4 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs537357318, COSV100846415; called by muse, mutect2, varscan2
- ROCK2 | c.3170G>A p.R1057Q | Missense Mutation (SNP) | VAF 83/380 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV59960185; called by muse, mutect2, varscan2
- TIAL1 | c.816C>G p.C272W | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64843062; called by muse, mutect2, varscan2
- ABCC11 | c.3520G>C p.V1174L | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CCDC88C | c.3569G>C p.R1190P | Missense Mutation (SNP) | VAF 112/250 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CDH4 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 120/646 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYSRT1 | c.331G>T p.G111C (on ENST00000409414; = p.G71C on NM_199001.5) | Missense Mutation (SNP) | VAF 87/198 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- DDC | c.1235G>C p.R412P | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM71E2 | c.621G>T p.K207N | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); called by mutect2, varscan2
- LRP1 | c.7330C>G p.R2444G | Missense Mutation (SNP) | VAF 91/423 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- PIK3C2B | c.1375C>A p.L459I | Missense Mutation (SNP) | VAF 35/517 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PKD2L1 | c.1517T>A p.F506Y | Missense Mutation (SNP) | VAF 101/279 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- PLCH2 | c.1142A>G p.E381G | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SEPTIN4 | c.670C>T p.L224F | Missense Mutation (SNP) | VAF 62/362 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SLC17A9 | c.201C>A p.S67R | Missense Mutation (SNP) | VAF 74/393 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC9A2 | c.124del p.A42Pfs*66 | Frame Shift Del (DEL) | VAF 36/161 reads (22%) | called by mutect2, pindel, varscan2
- ST8SIA1 | c.742G>C p.V248L | Missense Mutation (SNP) | VAF 104/483 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- STRN3 | c.402A>C p.K134N | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SUPT4H1 | c.337A>G p.T113A | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.055); called by muse, mutect2
- TRIM43B | c.82A>G p.I28V | Missense Mutation (SNP) | VAF 110/599 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- TTN | c.32895G>T p.K10965N (on ENST00000591111; = p.K10038N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/165 reads (32%) | PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- USP54 | c.313A>C p.K105Q | Missense Mutation (SNP) | VAF 88/250 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ARHGAP44 | c.2046C>G p.T682= | Silent (SNP) | VAF 95/199 reads (48%) | called by muse, mutect2, varscan2
- BAZ1A | c.1476A>G p.V492= | Silent (SNP) | VAF 62/219 reads (28%) | called by muse, mutect2, varscan2
- CROCC2 | c.879G>T p.R293= | Silent (SNP) | VAF 67/243 reads (28%) | catalogued as COSV70369370; called by muse, mutect2, varscan2
- FLII | c.918T>C p.F306= | Silent (SNP) | VAF 16/398 reads (4%) | called by muse, mutect2
- RAPGEF4 | c.2631C>A p.R877= | Silent (SNP) | VAF 36/440 reads (8%) | called by muse, mutect2
- SLC2A3 | c.486C>T p.I162= | Silent (SNP) | VAF 66/383 reads (17%) | catalogued as rs150412980; called by muse, mutect2, varscan2
- TMEM236 | c.771C>T p.H257= | Silent (SNP) | VAF 42/206 reads (20%) | called by muse, mutect2
- AL121900.1 | c.-3C>T | 5'UTR (SNP) | VAF 13/428 reads (3%) | catalogued as rs945361896; called by muse, mutect2
- C8orf48 | c.*83A>T | 3'UTR (SNP) | VAF 16/64 reads (25%) | called by muse, varscan2
- CHD8 | c.*21T>G | 3'UTR (SNP) | VAF 36/120 reads (30%) | called by muse, mutect2, varscan2
- CTR9 | c.*53A>G | 3'UTR (SNP) | VAF 41/66 reads (62%) | called by muse, mutect2, varscan2
- DUSP23 | c.*97C>G | 3'UTR (SNP) | VAF 20/51 reads (39%) | catalogued as COSV100929145; called by muse, mutect2, varscan2
- FUBP1 | c.211+860G>C | Intron (SNP) | VAF 35/136 reads (26%) | called by muse, mutect2, varscan2
- GRIK4 | c.2266+37G>T | Intron (SNP) | VAF 89/138 reads (64%) | called by mutect2, varscan2
- INPP5J | c.1272-21C>G | Intron (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- MUC19 | n.20178G>T | RNA (SNP) | VAF 56/239 reads (23%) | called by muse, mutect2, varscan2
- NPEPL1 | c.1302+47G>T | Intron (SNP) | VAF 92/371 reads (25%) | called by muse, mutect2, varscan2
- TGM2 | c.1616-19C>G | Intron (SNP) | VAF 56/254 reads (22%) | called by muse, mutect2, varscan2
- VAMP1 | c.341-24G>A | Intron (SNP) | VAF 33/145 reads (23%) | called by muse, mutect2, varscan2
